Somatic mutation profile of tumor specimen HCM-CSHL-0322-C20-01B (aliquot HCM-CSHL-0322-C20-01B-01D-A79C-36) from HCMI case HCM-CSHL-0322-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 69.1 years (25,229 days).
Specimen HCM-CSHL-0322-C20-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dca6e10d-517f-4b79-9949-1ac7bd0bd3d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0322-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0322-C20-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dffd41a-fcec-4aa1-bd0e-d4c9047741ef

The open-access MAF lists 81 somatic variants for this specimen: 61 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 18, Nonsense Mutation 6, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 124/302 reads (41%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 101/281 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 156/254 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); catalogued as rs758992299, COSV53124024; called by muse, mutect2, varscan2
- ADD2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs141431061; called by muse, mutect2, varscan2
- ARHGEF10 | c.3961C>T p.R1321C (on ENST00000398564; = p.R1296C on NM_014629.4) | Missense Mutation (SNP) | VAF 120/225 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs747279075, COSV50683984; called by muse, mutect2, varscan2
- ARSI | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs541439593; called by muse, mutect2, varscan2
- ATG7 | c.1625A>G p.N542S | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as rs752093920; called by muse, mutect2, varscan2
- BMP15 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868942078, COSV53139709; called by muse, mutect2, varscan2
- BTNL3 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201534771, COSV61565707, COSV61566065; called by muse, mutect2, varscan2
- CACNA1H | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.819); catalogued as rs1332969846; called by muse, mutect2
- CHRM2 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV57775959; called by muse, mutect2, varscan2
- CLDN17 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767649088, COSV99729012; called by muse, mutect2, varscan2
- COL17A1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768224335, COSV100793172; called by muse, mutect2, varscan2
- CSMD3 | c.7324C>T p.R2442* (on ENST00000297405 / NM_001363185.1; = p.R2338* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 191/393 reads (49%) | catalogued as rs995871749, COSV52274871; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 54/194 reads (28%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- ESPNL | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs570616030, COSV58032853; called by muse, mutect2, varscan2
- FIBCD1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs1392793644, COSV53395768; called by muse, mutect2, varscan2
- FRMD8 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.385); catalogued as rs776360172; called by muse, mutect2, varscan2
- GALNT9 | c.1328G>A p.R443H (on ENST00000328957 / NM_001122636.2; = p.R77H on NM_021808.3) | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs763432318, COSV61095686; called by muse, mutect2, varscan2
- GPR50 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.729); catalogued as rs1157091999; called by muse, varscan2
- GRIK1 | c.2755dup p.I919Nfs*8 (on ENST00000327783 / NM_001330994.2; = p.I875Nfs*8 on NM_175611.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 46/270 reads (17%) | catalogued as rs1200907182; called by mutect2, varscan2
- HNF4A | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 183/412 reads (44%) | catalogued as rs1413742263, COSV57381479; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- IGHE | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs782170045; called by muse, mutect2, varscan2
- KCNQ5 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV59669471; called by muse, mutect2, varscan2
- KLHL12 | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV100935891; called by muse, mutect2
- LIPE | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.197); catalogued as rs1296210753; called by muse, mutect2, varscan2
- PCDH17 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs760953125, COSV64976241, COSV64979321; called by muse, mutect2
- PCDHB7 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV50788951; called by muse, mutect2
- PDGFRA | c.3009G>A p.W1003* | Nonsense Mutation (SNP) | VAF 49/247 reads (20%) | catalogued as COSV57272140; called by muse, mutect2, varscan2
- PREX1 | c.3805C>A p.R1269S | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV64257888; called by muse, mutect2
- PRKCG | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV54724264; called by muse, mutect2, varscan2
- PROM1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 99/273 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs375364598; called by muse, mutect2, varscan2
- RABL6 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV99051474; called by mutect2, varscan2
- SDK1 | c.4439C>G p.P1480R | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770812300; called by muse, mutect2, varscan2
- TNIP1 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs139724991; called by muse, mutect2, varscan2
- VEGFC | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs769325515; called by muse, mutect2, varscan2
- ZNF442 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs770731530; called by muse, mutect2, varscan2
- ZNRF4 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199529322; called by muse, mutect2, varscan2
- ADAMTS16 | c.2404A>T p.T802S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.077); called by muse, mutect2
- CTCFL | c.1636T>C p.Y546H | Missense Mutation (SNP) | VAF 206/737 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.022); called by muse, mutect2
- DMRTB1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DZIP1L | c.1703A>G p.E568G | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- FRMPD1 | c.3860T>C p.I1287T | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GMPPA | c.491T>A p.V164E | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- HNRNPCL2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC7 | c.3347G>T p.G1116V (on ENST00000651989 / NM_001370785.2; = p.G1083V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- MYO1H | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEU2 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NLRP1 | c.1263G>T p.E421D | Missense Mutation (SNP) | VAF 114/198 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR51I1 | c.259T>A p.F87I | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RARS2 | c.1232T>A p.I411N | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RRAGA | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- SCN9A | c.5429A>G p.D1810G (on ENST00000303354; = p.D1799G on NM_002977.3) | Missense Mutation (SNP) | VAF 115/383 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- STAT1 | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); called by muse, mutect2
- SYTL3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USH2A | c.536T>A p.I179K | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- USP9X | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF667 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.13269C>T p.D4423= | Silent (SNP) | VAF 80/201 reads (40%) | catalogued as rs202130765, COSV60909433; called by muse, mutect2, varscan2
- CFAP77 | c.906G>A p.R302= | Silent (SNP) | VAF 63/252 reads (25%) | catalogued as rs758982709; called by muse, mutect2, varscan2
- COL6A5 | c.1851C>T p.C617= | Silent (SNP) | VAF 31/235 reads (13%) | catalogued as rs961502121; called by muse, mutect2, varscan2
- CTSG | c.450C>T p.V150= | Silent (SNP) | VAF 137/355 reads (39%) | called by muse, mutect2, varscan2
- DRC1 | c.1896C>T p.F632= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as rs748628980, COSV55522594; called by muse, mutect2, varscan2
- DSG1 | c.696G>A p.Q232= | Silent (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- FUT3 | c.603G>A p.K201= | Silent (SNP) | VAF 87/302 reads (29%) | called by muse, mutect2, varscan2
- GRIN3A | c.1785C>T p.F595= | Silent (SNP) | VAF 70/284 reads (25%) | catalogued as rs369210508; called by muse, mutect2
- HERC5 | c.2622C>T p.N874= | Silent (SNP) | VAF 80/213 reads (38%) | catalogued as rs762515665, COSV52037656, COSV52037916; called by muse, mutect2, varscan2
- KCNA4 | c.1641G>A p.A547= | Silent (SNP) | VAF 43/263 reads (16%) | catalogued as rs368797575, COSV100069314; called by muse, mutect2, varscan2
- NALCN | c.4140C>T p.T1380= | Silent (SNP) | VAF 54/620 reads (9%) | catalogued as rs753635783; called by muse, mutect2
- OR4C5 | c.672T>C p.S224= | Silent (SNP) | VAF 73/265 reads (28%) | catalogued as rs762231003; called by muse, mutect2, varscan2
- RAPGEF5 | c.678T>G p.L226= (on ENST00000401957 / NM_001367602.2; = p.L529= on NM_012294.5) | Silent (SNP) | VAF 12/382 reads (3%) | called by muse, mutect2
- SLC7A7 | c.1533C>T p.N511= | Silent (SNP) | VAF 11/237 reads (5%) | called by muse, mutect2
- TFPI2 | c.51G>A p.T17= | Silent (SNP) | VAF 12/323 reads (4%) | called by muse, mutect2
- THSD7A | c.4341G>A p.P1447= | Silent (SNP) | VAF 92/492 reads (19%) | catalogued as rs762226111, COSV70267009; called by muse, mutect2, varscan2
- TTN | c.1449C>T p.A483= | Silent (SNP) | VAF 132/441 reads (30%) | catalogued as rs141617218; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZFR2 | c.162G>A p.P54= | Silent (SNP) | VAF 33/242 reads (14%) | catalogued as rs756593762, COSV53603470; called by muse, mutect2, varscan2
- NELL1 | c.56-3386C>G | Intron (SNP) | VAF 9/269 reads (3%) | called by muse, mutect2
- SLC12A5 | c.121+1511C>T | Intron (SNP) | VAF 260/716 reads (36%) | catalogued as rs1164831768; called by muse, mutect2, varscan2
